Somatic mutation profile of tumor specimen MP2PRT-PARJZU-TMP1-B (aliquot MP2PRT-PARJZU-TMP1-B-1-0-D-A83C-36) from MP2PRT case MP2PRT-PARJZU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.3 years (1,222 days).
Specimen MP2PRT-PARJZU-TMP1-B: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f56a0c4c-b618-43f1-8807-ebee237e9bbc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PARJZU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PARJZU-NB1-A-1-0-D-A83C-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/02616eec-baeb-4992-a7a8-b5952e06cb9a

The open-access MAF lists 23 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 113/400 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ANKRD36 | c.1283C>T p.T428M | Missense Mutation (SNP) | VAF 18/79 reads (23%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.985); catalogued as rs567234399; called by muse, mutect2, varscan2
- EN1 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 175/656 reads (27%) | catalogued as COSV99727444; called by muse, mutect2, varscan2
- NOS1 | c.562G>A p.A188T | Missense Mutation (SNP) | VAF 144/505 reads (29%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs529671468, COSV57607848; called by muse, mutect2, varscan2
- NSD2 | c.3295G>A p.E1099K | Missense Mutation (SNP) | VAF 117/427 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs772470710, COSV56386422; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- OR10S1 | c.290G>T p.G97V | Missense Mutation (SNP) | VAF 119/392 reads (30%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV73343103; called by muse, mutect2, varscan2
- OS9 | c.506G>A p.R169H | Missense Mutation (SNP) | VAF 135/405 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs759106980, COSV57782843; called by muse, mutect2, varscan2
- TAF1 | c.3086G>A p.R1029H (on ENST00000373790 / NM_138923.4; = p.R1050H on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 165/344 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52117959; called by muse, mutect2, varscan2
- CCDC141 | c.3634G>C p.D1212H | Missense Mutation (SNP) | VAF 96/308 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- CCDC33 | c.24C>G p.N8K | Missense Mutation (SNP) | VAF 81/310 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- EPHA3 | c.1578T>G p.F526L | Missense Mutation (SNP) | VAF 110/476 reads (23%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- GFRA4 | c.104C>G p.A35G | Missense Mutation (SNP) | VAF 295/967 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.565); called by muse, mutect2
- IGLV3-10 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 120/388 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, varscan2
- LVRN | c.328G>C p.E110Q | Missense Mutation (SNP) | VAF 159/643 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- MAMSTR | c.1005C>A p.F335L (on ENST00000318083 / NM_001130915.2; = p.F232L on NM_182574.2) | Missense Mutation (SNP) | VAF 101/477 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- NCOA7 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 75/297 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.811); called by muse, mutect2, varscan2
- OR4C46 | c.87T>A p.F29L | Missense Mutation (SNP) | VAF 106/361 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- ETV7 | c.834G>A p.K278= | Silent (SNP) | VAF 70/366 reads (19%) | called by muse, mutect2, varscan2
- MYO5B | c.2208C>T p.P736= | Silent (SNP) | VAF 86/280 reads (31%) | catalogued as rs142276366; called by muse, mutect2, varscan2
- NRXN3 | c.2445G>A p.T815= (on ENST00000335750 / NM_001330195.2; = p.T442= on NM_004796.6) | Silent (SNP) | VAF 140/485 reads (29%) | catalogued as rs371473443; called by muse, mutect2, varscan2
- OBSL1 | c.3882C>T p.S1294= | Silent (SNP) | VAF 73/1001 reads (7%) | catalogued as rs775340849, COSV54704727; called by muse, mutect2
- OR13C9 | c.678C>T p.L226= | Silent (SNP) | VAF 74/335 reads (22%) | catalogued as COSV52242941, COSV52243663; called by muse, mutect2, varscan2
- POLR2J | c.285C>T p.I95= | Silent (SNP) | VAF 196/758 reads (26%) | catalogued as rs761476150; called by muse, mutect2, varscan2
